Somatic mutation profile of tumor specimen C3L-03721-01 (aliquot CPT0234700006) from CPTAC case C3L-03721, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 57.3 years (20,911 days).
Specimen C3L-03721-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99c70f73-4576-4092-9bff-b28db558857d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03721-31 (Blood Derived Normal), aliquot CPT0235670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4389324d-b046-4bcf-8876-05de2515e1f0

The open-access MAF lists 144 somatic variants for this specimen: 106 protein-altering or splice-affecting, 18 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 18, Intron 14, Nonsense Mutation 9, Frame Shift Del 7, 5'Flank 3, Frame Shift Ins 2, RNA 2, Splice Region 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 59/401 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 84/307 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881972, CM100600, COSV58825182, COSV58825894, COSV58830846; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADH5 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181904468; called by muse, mutect2, varscan2
- AFTPH | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1025960424; called by muse, mutect2, varscan2
- C17orf78 | c.398dup p.L133Ffs*8 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | catalogued as rs1024564984; called by mutect2, pindel, varscan2
- CCN5 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV51936908; called by muse, mutect2, varscan2
- CCN5 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs948505875, COSV51939417; called by muse, mutect2, varscan2
- CHIA | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303343353; called by muse, mutect2
- DCAF4L2 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 130/464 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV60478939; called by muse, mutect2, varscan2
- DYNC1LI1 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs750122388; called by muse, mutect2, varscan2
- FOXC2 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 134/442 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202926077; called by muse, mutect2, varscan2
- GABRA2 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.957); catalogued as COSV62916352; called by muse, mutect2, varscan2
- GPR157 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764427384, COSV66233724, COSV66234083; called by muse, mutect2, varscan2
- HK3 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 102/432 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs776797141, COSV52842032; called by muse, mutect2, varscan2
- IMMP2L | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59261471; called by muse, mutect2, varscan2
- KDR | c.2875C>A p.L959M | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.724); catalogued as COSV55771078; called by muse, mutect2, varscan2
- KEAP1 | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50305678; called by muse, varscan2
- KIR3DL1 | c.309del p.T104Lfs*11 | Frame Shift Del (DEL) | VAF 39/184 reads (21%) | catalogued as COSV100428392; called by mutect2, pindel, varscan2
- KSR2 | c.2230G>T p.G744* | Nonsense Mutation (SNP) | VAF 63/260 reads (24%) | catalogued as COSV100196387, COSV100196487; called by muse, mutect2, varscan2
- LRP5 | c.3976C>T p.R1326C | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs931097381, COSV53723809, COSV99592107; called by muse, mutect2
- LRRTM4 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1358722851; called by muse, varscan2
- MDM1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100291567; called by muse, mutect2, varscan2
- MPV17L | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55008899; called by muse, mutect2, varscan2
- NDST3 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs772812617; called by muse, mutect2, varscan2
- NFE2L3 | c.1828G>C p.V610L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs769409170; called by muse, mutect2, varscan2
- NOP9 | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 12/318 reads (4%) | catalogued as COSV99852118; called by muse, mutect2
- PAPSS1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | catalogued as COSV99491976; called by muse, mutect2, varscan2
- QTRT2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1278201636; called by muse, mutect2
- RBM10 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 96/186 reads (52%) | catalogued as COSV61310856; called by muse, mutect2, varscan2
- SAMD9L | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 39/114 reads (34%) | catalogued as COSV59079240; called by muse, mutect2, varscan2
- SLC2A3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV50006921; called by muse, mutect2, varscan2
- TCIRG1 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 164/668 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.811); catalogued as rs764312517, COSV55837809; called by muse, mutect2, varscan2
- TEX37 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 134/551 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as COSV57555387, COSV57556021; called by muse, mutect2, varscan2
- TRAV8-3 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs956640119; called by muse, mutect2, varscan2
- ZHX3 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752290331, COSV58381356; called by muse, mutect2, varscan2
- ZNF519 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73913264; called by muse, mutect2
- ACSM5 | c.415+1G>C p.X139_splice | Splice Site (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2498C>G p.A833G | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CBLIF | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 106/398 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CCDC63 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CDH10 | c.776T>A p.L259Q | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEBPZ | c.2968_2969del p.M990Gfs*5 | Frame Shift Del (DEL) | VAF 28/161 reads (17%) | called by pindel, varscan2
- CNGB3 | c.1377G>T p.M459I | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CNKSR2 | c.2543C>A p.P848H | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.3864del p.P1289Qfs*49 | Frame Shift Del (DEL) | VAF 62/247 reads (25%) | called by mutect2, pindel, varscan2
- CUL3 | c.699del p.Y233* | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | called by mutect2, pindel, varscan2
- CYP2C9 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 139/666 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCT | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 15/464 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX11 | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 91/358 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DDX3X | c.632_644del p.P211Rfs*5 (on ENST00000399959; = p.P212Rfs*5 on NM_001356.5) | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- DERPC | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DNAJC14 | c.2066A>G p.K689R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DSP | c.3621del p.N1208Tfs*42 | Frame Shift Del (DEL) | VAF 71/396 reads (18%) | called by mutect2, pindel, varscan2
- DUOX2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ECSCR | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ENPP6 | c.223dup p.Y75Lfs*11 | Frame Shift Ins (INS) | VAF 37/160 reads (23%) | called by mutect2, pindel
- FAM181B | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FILIP1L | c.2218C>A p.Q740K (on ENST00000354552 / NM_182909.3; = p.Q500K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL2 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GIMAP6 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GRM6 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 90/426 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GYPC | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGA4 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.7721G>T p.R2574L (on ENST00000360013 / NM_001024660.4; = p.R877L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KNDC1 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KNL1 | c.685_687delinsTT p.V229Lfs*11 (on ENST00000346991 / NM_170589.5; = p.V203Lfs*11 on NM_144508.5) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by pindel, varscan2*
- LRRIQ3 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MATN3 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.5350G>T p.E1784* | Nonsense Mutation (SNP) | VAF 66/322 reads (20%) | called by muse, mutect2, varscan2
- NEURL1 | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NINL | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUTM1 | c.1132C>A p.L378M | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- OAS1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- OR10V1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OVOL3 | c.584G>C p.G195A (on ENST00000585332; = p.G171A on NM_001302757.1) | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH10 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2
- PDE8A | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKG2 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 147/564 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PIAS1 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- PKD1L1 | c.5637C>A p.H1879Q | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PROM2 | c.2158G>C p.A720P | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PRSS37 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2
- RBP3 | c.3392A>T p.E1131V | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RSKR | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- RUFY1 | c.1906-8C>G | Splice Region (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- SBF1 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SGIP1 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC22A23 | c.456G>C p.W152C | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLC6A1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SNAPC3 | c.453A>T p.R151S | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPAG9 | c.1807A>G p.K603E (on ENST00000262013 / NM_001130528.3; = p.K589E on NM_003971.6) | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SPATA31A1 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- STRIP2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TRPC1 | c.2272G>T p.V758L (on ENST00000476941 / NM_001251845.2; = p.V724L on NM_003304.4) | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- TTC23L | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TTYH1 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- UNC5D | c.1943T>A p.M648K | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- VAMP7 | c.659A>T p.K220I | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- VPS50 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VSX1 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 106/425 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WAC | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFP30 | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF404 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF415 | c.1151A>T p.Y384F | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ZSCAN1 | c.1146T>A p.C382* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- CNOT11 | c.588C>T p.L196= | Silent (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- CSTF2T | c.429G>A p.L143= | Silent (SNP) | VAF 149/330 reads (45%) | catalogued as COSV58656141, COSV58657111; called by muse, mutect2, varscan2
- FMO2 | c.1056G>C p.L352= | Silent (SNP) | VAF 45/253 reads (18%) | called by muse, mutect2, varscan2
- FSCB | c.1203T>C p.A401= | Silent (SNP) | VAF 61/247 reads (25%) | catalogued as rs776935902; called by muse, mutect2, varscan2
- GIMAP6 | c.250C>A p.R84= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV61033801; called by muse, mutect2, varscan2
- HERC2 | c.6792T>A p.P2264= | Silent (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4527A>C p.G1509= | Silent (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- LRRC37B | c.2337G>T p.S779= | Silent (SNP) | VAF 141/531 reads (27%) | called by muse, mutect2, varscan2
- MUC17 | c.8238T>A p.P2746= | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- NAV3 | c.5343G>T p.V1781= | Silent (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- NOX5 | c.1845C>T p.P615= | Silent (SNP) | VAF 81/288 reads (28%) | called by muse, mutect2, varscan2
- OR2AG2 | c.498C>A p.L166= | Silent (SNP) | VAF 75/317 reads (24%) | catalogued as COSV58455172; called by muse, mutect2, varscan2
- PCDHGA3 | c.1221C>A p.A407= | Silent (SNP) | VAF 45/187 reads (24%) | called by muse, mutect2, varscan2
- SCYL3 | c.1173C>A p.S391= | Silent (SNP) | VAF 48/213 reads (23%) | called by muse, mutect2, varscan2
- SLC6A5 | c.2220C>A p.A740= | Silent (SNP) | VAF 87/437 reads (20%) | called by muse, mutect2, varscan2
- TANGO6 | c.1893T>C p.T631= | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- TAS1R1 | c.756C>A p.G252= | Silent (SNP) | VAF 93/317 reads (29%) | called by muse, mutect2, varscan2
- ZNF534 | c.1233A>G p.A411= (on ENST00000332323 / NM_001143939.3; = p.A398= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- ABCG8 | c.322+10A>T | Intron (SNP) | VAF 143/478 reads (30%) | catalogued as rs766026570; called by muse, mutect2, varscan2
- ADAMTS20 | c.2080-21G>C | Intron (SNP) | VAF 28/118 reads (24%) | called by mutect2, varscan2
- AL353804.4 | chrX:73821738 C>A | 5'Flank (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500349 A>C | 5'Flank (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- AP4M1 | c.463-22G>C | Intron (SNP) | VAF 29/906 reads (3%) | called by muse, mutect2
- CCDC107 | chr9:35657865 del T | 5'Flank (DEL) | VAF 82/369 reads (22%) | called by mutect2, pindel, varscan2
- CCDC85C | c.*13900G>A | 3'UTR (SNP) | VAF 49/147 reads (33%) | catalogued as rs781579005; called by muse, mutect2, varscan2
- CSMD1 | c.6245-10311G>C | Intron (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- FGFR4 | c.92-30G>T | Intron (SNP) | VAF 75/335 reads (22%) | catalogued as rs1421785410; called by muse, mutect2, varscan2
- GABRG2 | c.1248+290G>T | Intron (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+153G>T | Intron (SNP) | VAF 28/162 reads (17%) | catalogued as rs1330503617; called by muse, mutect2, varscan2
- LINC01193 | n.819C>G | RNA (SNP) | VAF 135/841 reads (16%) | catalogued as rs768341723; called by muse, mutect2, varscan2
- MACF1 | c.15832-11295A>C | Intron (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- MADD | c.4722+68C>T | Intron (SNP) | VAF 103/386 reads (27%) | catalogued as rs1449885334; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+63G>A | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as rs1441959547; called by muse, mutect2, varscan2
- NAIPP4 | n.2305del | RNA (DEL) | VAF 7/41 reads (17%) | called by mutect2, varscan2
- PLCE1 | c.1810-36A>G | Intron (SNP) | VAF 146/372 reads (39%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1058+104G>T | Intron (SNP) | VAF 74/265 reads (28%) | called by muse, mutect2, varscan2
- SORL1 | c.3461-433C>T | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- STK25 | c.-101+83del | Intron (DEL) | VAF 4/7 reads (57%) | called by mutect2, varscan2
